Somatic mutation profile of tumor specimen TCGA-06-0881-01A (aliquot TCGA-06-0881-01A-02D-1492-08) from TCGA case TCGA-06-0881, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 50.0 years (18,278 days).
Specimen TCGA-06-0881-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6a802887-3108-4770-b657-28f87cd4b991.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0881-10A (Blood Derived Normal), aliquot TCGA-06-0881-10A-01D-1492-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/00c046a5-b243-4f40-b107-bcd1c07d0918

The open-access MAF lists 13 somatic variants for this specimen: 11 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 11, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.866C>T p.A289V | Missense Mutation (SNP) | VAF 91/520 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs149840192, COSV51765841, COSV51768139; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.314G>A p.C105Y | Missense Mutation (SNP) | VAF 14/166 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587782343, CM991080, COSV64290665, COSV64299259, COSV64307337; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2
- CCDC47 | c.1093G>A p.V365M | Missense Mutation (SNP) | VAF 8/186 reads (4%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.875); catalogued as COSV56722672; called by muse, mutect2
- CDH18 | c.1454C>T p.P485L | Missense Mutation (SNP) | VAF 25/188 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.206); catalogued as COSV99937407; called by muse, mutect2, varscan2
- CDH18 | c.1453C>G p.P485A | Missense Mutation (SNP) | VAF 27/191 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs750128928, COSV56972721; called by muse, mutect2, varscan2
- COL6A3 | c.8725G>A p.A2909T | Missense Mutation (SNP) | VAF 22/240 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0.059); catalogued as rs201917052, COSV55091157; ClinVar: likely benign; called by muse, mutect2
- CSMD1 | c.8269C>G p.L2757V (on ENST00000520002; = p.L2756V on NM_033225.6) | Missense Mutation (SNP) | VAF 6/149 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV59364868; called by muse, mutect2
- FGA | c.1766A>G p.Y589C | Missense Mutation (SNP) | VAF 8/207 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.408); catalogued as COSV57399340; called by muse, mutect2
- MYOM2 | c.1954G>A p.G652R | Missense Mutation (SNP) | VAF 9/189 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767972373, COSV50752769; called by muse, mutect2
- OR2G2 | c.158G>A p.R53H | Missense Mutation (SNP) | VAF 24/426 reads (6%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs1011627557, COSV60741672, COSV60742813; called by muse, mutect2
- SEMA3E | c.1991C>T p.T664M | Missense Mutation (SNP) | VAF 13/205 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.426); catalogued as rs375536813; ClinVar: uncertain significance; called by muse, mutect2
- PCDHB16 | c.1011G>T p.V337= | Silent (SNP) | VAF 15/154 reads (10%) | catalogued as COSV53368590; called by muse, mutect2, varscan2
- TUBB | c.81A>G p.E27= | Silent (SNP) | VAF 5/64 reads (8%) | catalogued as COSV58358166; called by muse, mutect2
